Somatic mutation profile of tumor specimen 0E0HQN from CCDI case PBCVAU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0HQN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4169a0c-ca59-4fd0-9d66-a9df2cacf061.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0HR0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be062ddf-b0b7-4445-a7fb-f455b38de445

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 2, 5'UTR 2, 3'UTR 1, Splice Site 1, Frame Shift Ins 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5428G>T p.D1810Y | Missense Mutation (SNP) | VAF 134/504 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58615443, COSV58615662, COSV58615890; called by muse, mutect2, varscan2
- ABCE1 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 66/590 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.177); catalogued as rs1007884016; called by muse, mutect2, varscan2
- CPO | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as rs759125914, COSV55938729; called by mutect2, varscan2
- CXCR3 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1349979497, COSV65461872; called by muse, mutect2
- HAT1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs779584849; called by muse, mutect2, varscan2
- KLHL12 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 157/554 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV66127065; called by muse, mutect2, varscan2
- SLC9A7 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 61/604 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV100092331; called by muse, mutect2, varscan2
- UGT3A1 | c.1535G>A p.R512K | Missense Mutation (SNP) | VAF 184/815 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.257); catalogued as rs772590552; called by mutect2, varscan2
- CDH9 | c.812G>C p.S271T | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- DICER1 | c.2807A>G p.Y936C | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDRF1 | c.2635dup p.S879Kfs*6 (on ENST00000356792 / NM_001202438.2; = p.S845Kfs*6 on NM_015608.2) | Frame Shift Ins (INS) | VAF 109/553 reads (20%) | called by mutect2, varscan2
- GPR1 | c.761C>A p.A254D | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- INTS9 | c.138-1G>T p.X46_splice | Splice Site (SNP) | VAF 65/558 reads (12%) | called by muse, mutect2, varscan2
- IPO8 | c.912G>A p.V304= | Splice Region (SNP) | VAF 17/314 reads (5%) | called by muse, mutect2
- ITIH6 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 26/544 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.345); called by muse, mutect2
- MET | c.200C>G p.T67S | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- NLRC5 | c.618C>T p.D206= | Silent (SNP) | VAF 89/499 reads (18%) | catalogued as rs752886380, COSV52648943; called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 13/313 reads (4%) | called by muse, mutect2
- EHBP1 | c.-43G>C | 5'UTR (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2
- HYDIN | c.6853+10C>A | Intron (SNP) | VAF 65/616 reads (11%) | called by muse, mutect2
- MFSD4A | c.231-24T>G | Intron (SNP) | VAF 63/222 reads (28%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
